Surgical pathology report (de-identified scan), TCGA case TCGA-JY-A93E, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University Health Network, specimen TCGA-JY-A93E-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Consultation Report

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: M [REDACTED]

Service: [REDACTED]

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Collected: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

Ordering MD: [REDACTED]

Copy To: [REDACTED]

Specimen(s) Received

1. Lymph-Node: COMMON HEPATIC NODES ST18
2. Lymph node: Lymph Node Station 20
3. Lymph node: SPLEMIC NODES ST19
4. Lymph node: INF. PULM. LIGAMENT ST9L
5. Lymph node: DIAPHRAGMATIC NODES ST15
6. Lymph node: AORTO-PULMONARY ST5
7. Lymph node: SUBCARINAL ST.7
8. Lymph node: LT LOW PARATRACHEAL ST4L
9. Lymph node: ST7 SUBCARINAL NODE
10. Lymph node: ST16 PARACARDIAL NODE
11. Lymph node: ST 17 LEFT GASTRIC NODES
12. Lymph node: ST8L LOWER PARAESOPHAGEAL LYMPH NODE
13. Lymph node: ST8M MIDDLE PARAESOPHAGEAL LYMPH NODE
14. Esophagus: PROXIMAL STOMACH, THORACIC ESOPHAGUS
15. Esophagus: FINAL ESOPHAGEAL MARGIN
16. Soft Tissue: EEA DONUTS
17. Stomach Resection: PROXIMAL STOMACH FINAL GASTRIC RESECTION MARGIN

ICD-O-3
Adenocarcinoma NOS 8140/3
Site Esophagus, distal third
0155
JW 4/18/14

Diagnosis

1. Lymph-Node: COMMON HEPATIC NODES ST18:
- lymph nodes x4: negative for carcinoma
2. Lymph node: Lymph Node Station 20:
- lymph nodes x4: negative for carcinoma
3. Lymph node: SPLEMIC NODES ST19:
- lymph nodes x4: negative for carcinoma
4. Lymph node: INF. PULM. LIGAMENT ST9L:
- lymph node x1: negative for carcinoma
5. Lymph node: DIAPHRAGMATIC NODES ST15:
- lymph nodes x3: negative for carcinoma
6. Lymph node: AORTO-PULMONARY ST5:
- lymph node x1: negative for carcinoma
7. Lymph node: SUBCARINAL ST.7:
- lymph nodes x3: negative for carcinoma

[REDACTED]

[page 2 of 5]
8. Lymph node: LT LOW PARATRACHEAL ST4L:
- portion of fibroadipose tissue, negative for carcinoma
9. Lymph node: ST7 SUBCARINAL NODE:
- lymph nodes x2: negative for carcinoma
10. Lymph node: ST16 PARACARDIAL NODE:
- lymph nodes x4: negative for carcinoma
11. Lymph node: ST 17 LEFT GASTRIC NODES:
- metastatic adenocarcinoma in 1/9 lymph nodes
12. Lymph node: ST8L LOWER PARAESOPHAGEAL LYMPH NODE:
- lymph nodes x5: negative for carcinoma
13. Lymph node: ST8M MIDDLE PARAESOPHAGEAL LYMPH NODE:
- lymph nodes x3: negative for carcinoma
14. Esophagus: PROXIMAL STOMACH, THORACIC ESOPHAGUS, resection:
- adenocarcinoma of distal esophagus, poorly differentiated, involving GE junction and proximal stomach, extending into adventitia – see synoptic data and comment
- metastatic adenocarcinoma in 1/43 lymph nodes (specimens #1 to #13)
- resection margins: negative for carcinoma
15. Esophagus: FINAL ESOPHAGEAL MARGIN:
- negative for carcinoma
16. Soft Tissue: EEA DONUTS:
- negative for carcinoma
17. Stomach Resection: PROXIMAL STOMACH FINAL GASTRIC RESECTION MARGIN:
- negative for carcinoma.

Comment

14. The tumor is a moderately to poorly differentiated adenocarcinoma, centered in the distal esophagus, extending through GE junction into proximal stomach. The surface of the tumor is ulcerated. The tumor invades adventitia and is ~ 0.1 cm from the adventitial surface at the closest point. The gastric part of the tumor mainly involves submucosa and muscularis propria with focal extension into perigastric fat. There is metastatic adenocarcinoma in 1/43 lymph nodes identified.

Synoptic Data

Clinical History:	Not known: .
Specimen:	Esophagus Proximal stomach
Procedure:	Esophagogastrectomy
Primary Tumor Site:	Distal esophagus (lower thoracic esophagus)
Additional Sites Involved by Tumor:	Esophagogastric junction (EGJ) Proximal stomach and esophagogastric junction
Relationship of Tumor to Esophagogastric Junction:	Tumor midpoint lies in the distal esophagus and tumor involves the esophagogastric junction Distance of tumor center from esophagogastric junction: 2.0 cm
Histologic Type:	Adenocarcinoma
Histologic Grade:	G3: Poorly differentiated
Tumor Size:	Greatest dimension: 3.0 cm Additional dimension: 2.7 cm

[page 3 of 5]
Surgical Pathology Consultation Report

Microscopic Tumor Extension: Additional dimension: 1.0 cm
Tumor invades through the muscularis propria into the periesophageal soft tissue (adventitia)
Proximal Margin: Uninvolved by invasive carcinoma
Uninvolved by dysplasia
Distal Margin: Uninvolved by invasive carcinoma
Uninvolved by dysplasia
Circumferential (Adventitial) or Deep Margin: Uninvolved by invasive carcinoma
All Margin Status
All margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 1.0 mm
Closest margin: Circumferential
Treatment Effect: No prior treatment
Lymph-Vascular Invasion: Present
Perineural Invasion: Present
TNM Descriptors: Not applicable: .
Primary Tumor (pT): pT3: Tumor invades adventitia
Regional Lymph Nodes (pN): pN1: Regional lymph node metastasis involving 1 to 2 nodes
Number of regional lymph nodes examined: 43
Number of regional lymph nodes involved: 1
Distant Metastasis (pM): Not applicable: .
Additional Pathologic Findings: *None identified

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Clinical History

ESOPHAGEAL CA

Gross Description

1. The specimen container is labeled with the patient's name and as "Lymph Node: Common hepatic nodes ST18" consists of multiple pieces of fatty tissue measuring in aggregate 2.3 x 2.3 x 0.7 cm received in 10% buffered formalin. Within the fatty tissue, multiple lymph nodes are identified measuring from 0.2 to 0.8 cm. The specimen is submitted in toto as follows:

1A- multiple lymph nodes.

1B- remainder of fatty tissue.

2. The specimen container is labeled with the patient's name and as "Lymph Node: Lymph node station 20" consists of multiple pieces of fatty tissue measuring from 0.3 x 0.2 x 0.2 to 1.2 x 0.7 x 0.5 cm received in 10% buffered formalin.
2A- submitted in toto.

3. The specimen container is labeled with the patient's name and as "Lymph Node: Splenic nodes ST19" consists of multiple pieces of fatty tissue measuring in aggregate 1.7 x 1.5 x 0.5 cm received in 10% buffered formalin.
3A- submitted in toto.

4. The specimen container is labeled with the patient's name and as "Lymph Node: Inferior pulmonary ligament ST9L" consists of two fragments of fatty tissue measuring 1.5 x 0.3 x 0.5 cm and 1.7 x 0.8 x 0.4 cm received in 10% buffered formalin.
4A- submitted in toto.

5. The specimen container is labeled with the patient's name and as "Lymph Node: Diaphragmatic nodes ST15" consists of 3 pieces of fatty tissue measuring from 0.5 x 0.3 x 0.2 cm to 3.5 x 1.5 x 0.7 cm received in 10% buffered formalin.

[page 4 of 5]
5A-5B- submitted in toto.

6. The specimen container is labeled with the patient's name and as "Lymph Node: Aorto- pulmonary ST5" consists of a fragment of yellow-brown tissue measuring 0.7 x 0.6 x 0.4 cm received in 10% buffered formalin.

6A- submitted in toto.

7. The specimen container is labeled with the patient's name and as "Lymph Node: Subcarinal ST7" consists of 3 pieces of yellow black tissue measuring from 0.7 x 0.3 x 0.1 cm to 0.8 x 0.5 x 0.4 cm received in 10% buffered formalin.

7A- submitted in toto.

8. The specimen container is labeled with the patient's name and as "Lymph Node: LT Low Paratracheal ST4L" consists of a fragment of yellow-brown tissue measuring 1.0 x 0.5 x 0.3 cm received in 10% buffered formalin.

8A- submitted in toto.

9. The specimen container is labeled with the patient's name and as "Lymph Node: ST7 Subcarinal Node" consists of a piece of black-brown tissue measuring 3.9 x 2.7 x 1.2 cm received in 10% buffered formalin.

9A-9B- specimen is bisected and submitted in toto.

10. The specimen container is labeled with the patient's name and as "Lymph Node: ST16 Paracardial node" consists of a piece of fatty tissue measuring 5.5 x 3.4 x 1.0 cm received in 10% buffered formalin. Within the fatty tissue, multiple lymph nodes are identified measuring from 0.5 cm to 1.2 cm. The specimen is submitted in toto as follows:

10A- multiple lymph nodes

10B-10C- remainder of fatty tissue.

11. The specimen container is labeled with the patient's name and as "Lymph Node: ST17 left gastric nodes" consists of a piece of fatty tissue measuring 4.0 x 3.8 x 2.7 cm received in 10% buffered formalin. Within the fatty tissue, multiple lymph nodes are identified measuring from 0.5 cm to 2.4 cm. Representative sections are submitted as follows:

11A- multiple lymph nodes.

11B-11C- one lymph node bisected.

11D-11H- fatty tissue.

12. The specimen container is labeled with the patient's name and as "Lymph Node: ST8L lower paraesophageal lymph node" consists of a piece of fatty tissue measuring 4.0 x 4.0 x 1.5 cm received in 10% buffered formalin. Within the fatty tissue, multiple lymph nodes are identified measuring from 0.3 to 0.6 cm. The specimen is submitted in toto as follows:

12A- multiple lymph nodes.

12B-12E- remainder of fatty tissue.

13. The specimen container is labeled with the patient's name and as "Lymph Node: ST8M middle paraesophageal lymph node" and consists of a piece of fatty tissue measuring 4.0 x 3.5 x 0.7 cm received in 10% buffered formalin. Within the fatty tissue, two lymph nodes are identified measuring 0.5 x 0.3 x 0.2 cm and 0.7 x 0.5 x 0.2 cm. The specimen is submitted in toto as follows:

13A- two lymph nodes

13B-13D- remainder of fatty tissue.

14. RESECTION SPECIMEN: Esophagus: Proximal stomach, thoracic esophagus (gastro esophagectomy)

FIXATION: Fixed

DIMENSIONS:

Stomach:

Length along lesser curvature: 4.4 cm

Length along greater curvature: 3.5 cm

Circumference of distal gastric margin: 11.0 cm

Esophagus:

Length of tubular esophagus: 6.9 cm

Width of tubular esophagus: 4.0 cm

TUMOR

[page 5 of 5]
Surgical Pathology Consultation Report

LOCATION:

- GE junction tumor
- 60% of tumor mass located in the esophagus and 40% of the tumor mass located in the proximal stomach

- CONFIGURATION: Polypoid and ulcerated

- DIMENSIONS: Diameters: 3.0 x 2.7 cm
Depth: 1.0 cm

- DESCRIPTIVE CHARACTERISTICS: Tan-brown ulcerated tumor mass with irregular heaped up edges

- PERFORATION: No

- DISTANCE FROM MARGINS:

- PROXIMAL: 3.4 cm
- DISTAL: 1.8 cm
- RADIAL: 0.1 cm (nonperitonealized soft tissue margin closest to deepest tumor penetration)

ESTIMATED DEPTH OF INVASION: Adventitia

LESIONS IN NONCANCEROUS STOMACH: None grossly

LYMPH NODES: No perigastric lymph nodes along the greater and lesser curvatures are identified from the specimen

Tissue stored frozen

Representative Sections:

- 14A- proximal esophageal margin en face
- 14B-14M- tumor submitted in toto, proximal to distal
- 14N- proximal esophagus
- 14O- distal gastric margin en face
- 14P- gastric wall
- 14Q- perigastric fat

15. The specimen container is labeled with the patient's name and as "Esophagus: Final esophageal margin consists of a piece of tan-brown tissue with one stapled edge measuring 1.8 x 0.7 x 0.7 cm received in 10% buffered formalin.

15A- submitted in toto after removal of the stapled line

16. The specimen container is labeled with the patient's name and as "Soft Tissue: EEA donuts" consists of a piece of tan-brown tissue measuring 2.3 x 1.0 x 0.8 cm received in 10% buffered formalin.

16A- submitted in toto.

17. The specimen container is labeled with the patient's name and as "Stomach Resection: Proximal stomach final gastric resection margin" consists of a portion of stomach with one stapled line measuring in 6.5 by 4.0 x 2.8 cm received in 10% buffered formalin. The stapled line margin is removed. Upon opening of the specimen, the gastric mucosa is tan-brown in color and is grossly unremarkable. Representative sections are submitted as follows:

17A-17C- stapled line margin en face

17D-17E- gastric wall.

Source: NCI Genomic Data Commons file cb2f37b6-9494-4a87-8ba6-3b84d144f9b4 (TCGA-JY-A93E.E69389E8-EC63-4B08-BD09-01C663D8B52D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).